Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6TV, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6TV-01A (Primary Tumor).

[REDACTED]
Histomorphology shows oligodendroglial and astrocytic differentiation. Minigemistocytes present. Proliferation index 8%. In conclusion, this tumor is already graded according to WHO grade III.

Diagnosis

Anaplastic Oligoastrocytoma WHO grade III

C&F ICD-O3
Oligoastrocytoma, grade III
9382/3
path
Oligoastrocytoma, anaplastic
9382/3
Site: Brain, supratentorial NC
C71.0
JW 7/25/13

Untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file df155f0a-a487-4d4b-a8f0-3c5643ba38a3 (TCGA-S9-A6TV.0D9D6080-A0B2-4198-ACDF-6F47D25491B7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).